Gene-level copy-number profile of tumor specimen TCGA-HB-A3YV-01A from TCGA case TCGA-HB-A3YV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 75.5 years (27,583 days).
Specimen TCGA-HB-A3YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.e7cddc48-9b99-4933-be70-4a3730cae2ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HB-A3YV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/528230d5-4ff4-4ff8-bd22-9bda30da9564

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1,373; copy number 2: 11,038; copy number 3: 17,782; copy number 4: 21,292; copy number 5: 3,962; copy number 6: 1,084; copy number 7: 1,002; copy number 8: 637; copy number 9: 753; copy number 10: 179; copy number 12: 59; copy number 13: 18; copy number 14: 15; copy number 15: 8; copy number 16: 106; copy number 17: 31; copy number 18: 64; copy number 19: 107; copy number 21: 25; copy number 22: 1; copy number 23: 32; copy number 24: 41; copy number 25: 11; copy number 26: 53; copy number 27: 2; copy number 28: 9; copy number 29: 5; copy number 32: 6; copy number 33: 16; copy number 35: 27; copy number 38: 8; copy number 40: 22; copy number 41: 6; copy number 46: 4; copy number 48: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HB-A3YV-01A-11D-A24M-01): tumor purity 0.88, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,531 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:48,727,519–52,573,816, 80 genes, copy number 9 (broad region; genes not listed).
- chr1:58,047,889–61,589,904, 40 genes, copy number 12: HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4.
- chr1:165,210,627–165,219,104, 2 genes, copy number 21: LMX1A-AS2, LMX1A-AS1.
- chr1:169,059,576–169,367,948, 6 genes, copy number 23 (within-gene range 3–23): AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1.
- chr4:212,610–5,709,548, 154 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr4:18,418,662–22,330,330, 25 genes, copy number 9: AC093898.1, AC093871.1, AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1, PACRGL, KCNIP4, AC097505.1, AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2, KCNIP4-IT1, AC096719.1, RNU6-420P.
- chr4:23,560,923–29,467,850, 68 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr4:139,015,781–142,847,432, 61 genes, copy number 9 (broad region; genes not listed).
- chr4:151,949,338–152,318,364, 11 genes, copy number 9: AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1, AC079340.2, RN7SL446P, AC080078.1, AC080078.2.
- chr4:153,633,692–153,760,024, 6 genes, copy number 12 (within-gene range 6–12): AC106865.2, AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1.
- chr4:166,312,935–169,612,627, 30 genes, copy number 9–26 (within-gene range 5–26): Y_RNA, AC097487.1, SPOCK3, RNA5SP171, AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1.
- chr6:39,792,298–44,830,188, 164 genes, copy number 16–19 (broad region; genes not listed).
- chr6:98,780,257–102,453,792, 36 genes, copy number 10–40 (within-gene range 10–44): AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2, AL357139.1.
- chr6:110,424,687–112,254,939, 44 genes, copy number 10 (within-gene range 3–10): SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1, MFSD4B, AL080317.1, REV3L, AL080317.2, FCF1P5, REV3L-IT1, BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1, FYN, LINC02527, CCN6, TUBE1, FAM229B, LAMA4, Z99289.1, RNU6-1226P, Z99289.2, Z99289.3.
- chr6:137,143,820–138,422,197, 22 genes, copy number 21: IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2.
- chr6:139,371,807–139,615,204, 3 genes, copy number 24: CITED2, LINC01625, ATP5PBP6.
- chr6:139,856,104–140,898,381, 6 genes, copy number 25–38 (within-gene range 3–38): AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2.
- chr6:140,761,529–141,020,026, 4 genes, copy number 25: RPS3AP24, AL035446.1, AL357084.1, AL357080.1.
- chr6:142,526,455–143,059,682, 8 genes, copy number 16: AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2.
- chr6:143,386,581–144,853,034, 27 genes, copy number 19 (within-gene range 3–35): AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1.
- chr6:150,326,623–153,427,154, 53 genes, copy number 9–35: RNU4-7P, IYD, SSR1P1, AL451061.1, PLEKHG1, AL450344.3, AL450344.1, AL450344.2, PDCL3P5, MTHFD1L, ARL4AP5, RNU6-302P, AL133260.2, AL138733.1, AL133260.1, AL138733.2, RNU6-300P, AL356535.1, AKAP12, RNU6-1247P, RNY4P20, RN7SKP268, ZBTB2, Y_RNA, RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1, SYNE1, SYNE1-AS1, AL049548.1, RNA5SP223, NANOGP11, MYCT1, HSPD1P16, VIP, LINC02840, TUBB4BP7, AL080276.1, FBXO5, AL080276.2, MTRF1L, RGS17, RNA5SP224, AL590867.1, AL590867.2, AL358134.1, RNA5SP225.
- chr6:153,938,433–154,834,244, 15 genes, copy number 17–46 (within-gene range 8–46): HMGB3P19, OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P.
- chr12:66,767–9,316,173, 335 genes, copy number 9 (broad region; genes not listed).
- chr12:50,923,472–51,028,566, 8 genes, copy number 26 (within-gene range 4–26): METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P.
- chr12:53,632,726–53,677,408, 2 genes, copy number 19 (within-gene range 4–19): ATP5MC2, AC073594.1.
- chr12:57,693,955–57,984,761, 27 genes, copy number 24: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:60,150,187–60,341,941, 3 genes, copy number 38 (within-gene range 4–38): AC087883.2, AC087883.1, Y_RNA.
- chr12:61,879,318–62,417,431, 7 genes, copy number 13–28 (within-gene range 4–50): KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P.
- chr12:63,558,913–64,162,217, 13 genes, copy number 9–48 (within-gene range 4–48): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2.
- chr12:64,186,316–64,397,065, 4 genes, copy number 28 (within-gene range 4–28): C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P.
- chr12:64,759,484–65,491,430, 16 genes, copy number 33 (within-gene range 4–33): TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:66,023,620–66,170,072, 8 genes, copy number 24: MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:67,709,047–68,234,686, 7 genes, copy number 19–27 (within-gene range 4–27): LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70.
- chr12:68,746,125–68,850,686, 6 genes, copy number 41 (within-gene range 21–41): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:69,212,108–69,699,476, 18 genes, copy number 17 (within-gene range 4–17): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:76,660,405–76,757,914, 3 genes, copy number 10: AC107032.1, RPL7P43, AC093014.1.
- chr12:80,935,736–81,759,553, 7 genes, copy number 15 (within-gene range 4–15): MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1.
- chr13:76,552,807–76,928,836, 6 genes, copy number 18–23 (within-gene range 1–23): AL136441.1, AL161717.1, AL365394.1, KCTD12, AC000403.1, BTF3P11.
- chr18:66,946,116–70,650,744, 52 genes, copy number 10–17: RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1, AC090337.1, AC090337.2, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P, GTSCR1.
- chr19:1,065,923–3,063,107, 123 genes, copy number 10–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
